Somatic mutation profile of tumor specimen MMRF_1080_1_BM_CD138pos (aliquot MMRF_1080_1_BM_CD138pos_T2_TSE61_K03608) from MMRF case MMRF_1080, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.6 years (24,337 days).
Specimen MMRF_1080_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67cd878c-91a5-4678-bfb6-f72a6a1d8c13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1080_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1080_1_PB_Whole_C1_TSE61_K03607; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2de5a462-6896-45d6-b60f-056cee37df71

The open-access MAF lists 73 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 20, Silent 12, Nonsense Mutation 4, Intron 3, 5'UTR 3, Frame Shift Del 2, 5'Flank 2, RNA 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 7/45 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, varscan2
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, varscan2
- ARHGAP25 | c.1084_1085del p.L362Vfs*8 (on ENST00000409202 / NM_001007231.3; = p.L354Vfs*8 on NM_014882.3) | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as rs1329001469; called by mutect2, pindel, varscan2
- BIRC6 | c.2996C>G p.S999* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV70206594; called by muse, mutect2, varscan2
- CACNA1E | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as rs1484841139, COSV62437802; called by muse, varscan2
- CRX | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 95/201 reads (47%) | catalogued as CM1514166; called by muse, mutect2, varscan2
- HK3 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs779887345; called by muse, mutect2, varscan2
- IFI44 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV66075690; called by muse, mutect2, varscan2
- IVD | c.1265A>G p.N422S (on ENST00000651168; = p.N419S on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/81 reads (77%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.632); catalogued as rs1055585260; called by muse, mutect2, varscan2
- MICAL2 | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs145746384; called by muse, mutect2, varscan2
- PCSK5 | c.2282G>A p.S761N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100949810; called by muse, mutect2, varscan2
- PKN3 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs778625869; called by muse, mutect2, varscan2
- PTPRK | c.2278A>T p.I760F (on ENST00000368215 / NM_001291984.2; = p.I761F on NM_002844.4) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV63893738; called by muse, mutect2, varscan2
- ACTRT2 | c.653_656del p.K218Sfs*21 | Frame Shift Del (DEL) | VAF 35/76 reads (46%) | called by mutect2, pindel, varscan2
- ALOX12B | c.2102T>C p.I701T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- BRPF1 | c.84C>G p.C28W | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CKAP2L | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COG2 | c.1832C>A p.A611D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EI24 | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- GGA2 | c.554T>C p.F185S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HPS5 | c.1736G>A p.C579Y (on ENST00000349215 / NM_181507.2; = p.C465Y on NM_007216.4) | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITIH2 | c.2169A>C p.E723D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2
- LASP1 | c.776A>T p.E259V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAMDC4 | c.2156C>T p.A719V (on ENST00000445819; = p.A640V on NM_206920.3) | Missense Mutation (SNP) | VAF 73/102 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MTHFSD | c.394G>T p.V132F (on ENST00000360900 / NM_001159377.2; = p.V131F on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MUC16 | c.38863A>T p.K12955* | Nonsense Mutation (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- RERGL | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RNF126 | c.790_792del p.D264del | In Frame Del (DEL) | VAF 18/37 reads (49%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- TOMM40L | c.736T>G p.F246V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TPR | c.3160G>A p.A1054T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ASXL2 | c.3495C>T p.D1165= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- DIPK1B | c.67C>A p.R23= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- DSG4 | c.1209A>G p.L403= | Silent (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2
- LMTK3 | c.1851C>T p.A617= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs985545935; called by muse, mutect2, varscan2
- LRRC30 | c.327G>C p.L109= | Silent (SNP) | VAF 10/64 reads (16%) | called by mutect2, varscan2
- MERTK | c.2892G>A p.R964= | Silent (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- MORN3 | c.372C>T p.S124= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs782815065, COSV100804463; called by muse, mutect2, varscan2
- MYO15A | c.4113T>C p.F1371= | Silent (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.1272C>T p.S424= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as rs1554230238; called by muse, mutect2, varscan2
- TEKT3 | c.1233G>A p.L411= | Silent (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- TRPM5 | c.2049G>A p.L683= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV50147859; called by muse, mutect2
- XIRP2 | c.4638G>A p.L1546= (on ENST00000628543; = p.L1721= on NM_152381.6) | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- AC131160.1 | c.*883G>A | 3'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs987786730; called by muse, mutect2, varscan2
- AGBL4 | c.*1088G>T | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- ANXA2R | c.-1391C>T | 5'UTR (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- ANXA5 | c.-121C>T | 5'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- CA10 | c.-1065_-1064insT | 5'UTR (INS) | VAF 16/30 reads (53%) | called by mutect2, pindel, varscan2
- CACNA1C | chr12:2693810 T>C | 3'Flank (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- CEP126 | c.*151A>C | 3'UTR (SNP) | VAF 11/122 reads (9%) | called by muse, mutect2
- ETS1 | c.*93dup | 3'UTR (INS) | VAF 14/128 reads (11%) | called by mutect2, pindel
- FAM53B | c.*3419A>C | 3'UTR (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- FOLR1 | c.-9+780del | Intron (DEL) | VAF 58/138 reads (42%) | called by mutect2, pindel, varscan2
- GPR62 | c.*422C>G | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- KLHL12 | c.*3A>G | 3'UTR (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100935901; called by muse, mutect2, varscan2
- KLHL41 | c.*13A>G | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- LINC00636 | n.100G>C | RNA (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- LONRF2 | c.*810A>C | 3'UTR (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- MFAP3L | c.*3689_*3691del | 3'UTR (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel, varscan2
- PDE4B | c.635-340G>A | Intron (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- PDP1 | c.*890G>A | 3'UTR (SNP) | VAF 5/68 reads (7%) | catalogued as COSV52601749; called by muse, mutect2
- PM20D2 | c.*3125T>A | 3'UTR (SNP) | VAF 7/37 reads (19%) | catalogued as rs1216997394; called by muse, mutect2, varscan2
- PMP22 | c.*587C>T | 3'UTR (SNP) | VAF 23/54 reads (43%) | catalogued as rs568822260; called by muse, mutect2, varscan2
- RFPL1 | c.374-222G>A | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- SEC14L1 | c.*1917G>C | 3'UTR (SNP) | VAF 22/456 reads (5%) | called by muse, mutect2
- SNX1 | c.*482A>G | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- SPINK6 | chr5:148203023 C>A | 5'Flank (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- STK4 | chr20:44966500 C>T | 5'Flank (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- THRB | c.*3014G>A | 3'UTR (SNP) | VAF 31/80 reads (39%) | catalogued as rs1331845345; called by muse, mutect2, varscan2
- TRIB1 | c.*1403dup | 3'UTR (INS) | VAF 14/150 reads (9%) | called by mutect2, pindel
- USP44 | c.*856dup | 3'UTR (INS) | VAF 30/64 reads (47%) | catalogued as rs1256962207; called by mutect2, varscan2
- ZFYVE1 | c.*1056C>A | 3'UTR (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- ZNF12 | c.*479G>A | 3'UTR (SNP) | VAF 10/134 reads (7%) | catalogued as rs1226788601; called by muse, mutect2
